MP2PRT case MP2PRT-PARYIG — Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia (MP2PRT-ALL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Acute Lymphoblastic Leukemia; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/1e2db587-ee66-48bf-91aa-2ad6fb4d2be0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 8 years; Year of birth: 1999; Vital status: Dead; Days to death: 946 days (2.6 years); Year of death: 2010.

Diagnoses (1)
1. Common precursor B ALL: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 8.8 years (3,201 days); Year of diagnosis: 2008; Days to last follow up: 946 days (2.6 years).
   Treatment given: Initial disease status: Initial Diagnosis; Regimen or line of therapy: SR-Average Group - IS arm:  Intensified Consolidation, Standard Interim Maintenance, Standard Delaye; Days to treatment start: 3 days; Days to treatment end: 568 days (1.6 years); Number of cycles: 5; Treatment outcome: Complete Response; Reason treatment ended: Disease Progression; Treatment anatomic sites: Body, total.

Follow-up (1 entry)
- Days to follow up: 946 days (2.6 years); Disease response: Complete Response; Progression or recurrence: Yes; Progression or recurrence anatomic site: Overlapping lesion of brain and central nervous system; Days to recurrence: 568 days (1.6 years).

Molecular and laboratory tests
- ABL1 (FISH): Negative.
- BCR (FISH): Negative.
- CRLF2 (Cytogenetics, NOS): Negative.
- ETV6 (FISH): Negative.
- KMT2A (FISH): Negative.
- RUNX1 (FISH): Negative.

Biospecimens (3 samples)
- Sample MP2PRT-PARYIG-NB1-A: Sample type: Blood Derived Cancer - Peripheral Blood, Post-treatment; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
- Samples MP2PRT-PARYIG-TMP1-A, MP2PRT-PARYIG-TMP1-B (2 with the same recorded description): Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
